Somatic mutation profile of tumor specimen C3L-01924-03 (aliquot CPT0114660010) from CPTAC case C3L-01924, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.4 years (25,001 days).
Specimen C3L-01924-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38541079-77cf-4f17-92d9-989c30487e4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01924-31 (Blood Derived Normal), aliquot CPT0116660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45bdc569-5ddd-4b67-91f3-af5a60760704

The open-access MAF lists 763 somatic variants for this specimen: 520 protein-altering or splice-affecting, 150 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 458, Silent 150, Intron 42, Nonsense Mutation 30, RNA 21, Splice Site 15, 3'UTR 14, Frame Shift Del 7, 5'UTR 7, Splice Region 6, 5'Flank 6, 3'Flank 3.

Variants (750 of 763; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 68/262 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MORC2 | c.754C>T p.R252W (on ENST00000397641 / NM_001303256.3; = p.R190W on NM_014941.3) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs864309503, CM160278, COSV53196061; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- MSH2 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 27/359 reads (8%) | catalogued as rs63750037, CM000181; ClinVar: pathogenic; called by muse, mutect2
- ABCA8 | c.3814T>C p.C1272R | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52196718; called by muse, mutect2
- ABCA8 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52207907; called by muse, mutect2, varscan2
- ADAMTS3 | c.300A>C p.Q100H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs751923787; called by muse, mutect2
- ADCY2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV57861474, COSV57862969; called by muse, mutect2, varscan2
- ADCY4 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as rs767827709, COSV99353606; called by muse, mutect2, varscan2
- ADGRB2 | c.1059G>T p.R353S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1195097574; called by muse, mutect2, varscan2
- ADGRG4 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 135/360 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs746689970; called by muse, mutect2, varscan2
- ADGRG6 | c.2998G>T p.G1000* | Nonsense Mutation (SNP) | VAF 33/225 reads (15%) | catalogued as COSV99746351; called by muse, mutect2, varscan2
- ALOX5 | c.555-2A>G p.X185_splice | Splice Site (SNP) | VAF 18/121 reads (15%) | catalogued as COSV104428486; called by muse, mutect2, varscan2
- AMIGO3 | c.948G>C p.Q316H | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57539361; called by muse, mutect2, varscan2
- AOAH | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1267800979, COSV99332373; called by muse, mutect2, varscan2
- ATP10B | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59163501; called by muse, mutect2, varscan2
- B3GAT1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs751288572; called by muse, mutect2, varscan2
- BICRAL | c.2212G>T p.V738L | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs202055883; called by muse, mutect2, varscan2
- BTBD11 | c.1742G>C p.R581P (on ENST00000280758 / NM_001018072.2; = p.R118P on NM_001017523.2) | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55024272; called by muse, mutect2, varscan2
- C1orf94 | c.902C>T p.P301L (on ENST00000488417 / NM_001134734.2; = p.P111L on NM_032884.5) | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1208422637; called by muse, mutect2
- CA2 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 30/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs886063150, COSV53406390; called by muse, mutect2
- CA2 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 49/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99570230; called by muse, mutect2, varscan2
- CACNA1H | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs928701675; called by muse, mutect2, varscan2
- CASR | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs775751453, CM123746, COSV56135650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCND1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as rs1299107729; called by muse, mutect2, varscan2
- CDC20 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs761756771, COSV60523215; called by muse, mutect2, varscan2
- CDH10 | c.1834G>T p.G612W | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369284486, COSV52594290; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62575290; called by muse, mutect2
- CFH | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as CM131602; called by muse, mutect2, varscan2
- CLDN20 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs201661997; called by muse, mutect2, varscan2
- COL3A1 | c.1865C>A p.P622H | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58594889; called by muse, mutect2
- COL6A3 | c.5393G>T p.R1798L | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV55100596; called by muse, mutect2
- CPN2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs1403331980, COSV100103313; called by muse, mutect2, varscan2
- CSMD3 | c.4615C>T p.R1539* (on ENST00000297405 / NM_001363185.1; = p.R1435* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 94/278 reads (34%) | catalogued as rs149308903, COSV52239671; called by muse, mutect2, varscan2
- CYBB | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 19/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM106235; called by muse, mutect2
- DAOA | c.328A>C p.N110H | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV61603044; called by muse, mutect2
- DISP3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as rs1372854383, COSV53823625; called by muse, mutect2, varscan2
- DMRTC2 | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV99523393; called by muse, mutect2, varscan2
- DNAH5 | c.10817C>T p.P3606L | Missense Mutation (SNP) | VAF 144/364 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX1414812; called by muse, mutect2, varscan2
- DNAH8 | c.4580C>G p.S1527C | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59426389; called by muse, mutect2, varscan2
- DTX4 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1204482444; called by muse, mutect2, varscan2
- EGF | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs373552129; called by muse, mutect2, varscan2
- EIF4G1 | c.1771G>T p.E591* (on ENST00000346169 / NM_198241.3; = p.E395* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 63/512 reads (12%) | catalogued as COSV59989363, COSV59991452; called by muse, mutect2, varscan2
- ENPP3 | c.2363A>C p.K788T | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as COSV62957018; called by muse, mutect2, varscan2
- EOGT | c.1355G>A p.R452H (on ENST00000383701 / NM_001278689.2; = p.R368H on NM_173654.3) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs193201126, COSV55154247; called by muse, mutect2, varscan2
- ERBB4 | c.262T>G p.L88V | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53575434; called by muse, mutect2
- ERGIC3 | c.562A>G p.S188G | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1406023294; called by muse, mutect2, varscan2
- EXO1 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs147687027; called by muse, mutect2, varscan2
- EYS | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV60983274; called by muse, varscan2
- F8 | c.3538G>C p.V1180L | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV64279172; called by muse, mutect2
- F9 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM940456, CM940457, CM990569; called by muse, mutect2, varscan2
- FAT4 | c.14062T>A p.S4688T | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.943); catalogued as rs756365567; called by muse, mutect2
- FBN2 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 67/439 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52521157; called by muse, mutect2, varscan2
- FBN2 | c.1295C>A p.S432Y | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.276); catalogued as rs1324648329; called by muse, mutect2, varscan2
- FLNC | c.4574C>T p.P1525L | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57967161; called by muse, mutect2
- FSIP2 | c.4590G>A p.M1530I | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs1487083470; called by muse, mutect2
- FSTL5 | c.1820C>A p.T607K | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1178977194; called by muse, mutect2, varscan2
- GABRA5 | c.609C>G p.Y203* | Nonsense Mutation (SNP) | VAF 47/221 reads (21%) | catalogued as COSV59475337; called by muse, mutect2, varscan2
- GFRAL | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 77/305 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs376345396, COSV61230941; called by muse, varscan2
- GFRAL | c.125G>T p.W42L | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1330893936; called by muse, varscan2
- GIMAP8 | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56234416; called by muse, mutect2, varscan2
- GPATCH2 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1558399521; called by muse, mutect2, varscan2
- GRK1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766150912, COSV59552691; called by muse, mutect2, varscan2
- GRM7 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV63133121; called by muse, mutect2
- GRM7 | c.1498G>T p.D500Y | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1161351035; called by muse, mutect2, varscan2
- GTF3C1 | c.3266G>T p.R1089L | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV62241085; called by muse, mutect2, varscan2
- H3C4 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV100587257; called by muse, mutect2
- H4C6 | c.221C>G p.T74R | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1009451491; called by muse, mutect2, varscan2
- HBB | c.93-6C>T | Splice Region (SNP) | VAF 42/391 reads (11%) | catalogued as rs1554918048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs867599481, COSV67785345; called by muse, mutect2, varscan2
- HECW2 | c.4099G>T p.D1367Y | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149188557; called by muse, mutect2, varscan2
- HEPH | c.2857C>A p.L953I (on ENST00000343002; = p.L686I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.486); catalogued as COSV57975170; called by muse, mutect2, varscan2
- HNF4G | c.700G>T p.D234Y (on ENST00000354370 / NM_001330561.2; = p.D281Y on NM_004133.5) | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62971120; called by muse, mutect2
- ICE1 | c.5546G>T p.R1849L | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56818744; called by muse, mutect2
- INSYN2B | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs981248621; called by muse, mutect2
- JAKMIP3 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100059523; called by muse, mutect2, varscan2
- KIF6 | c.1534C>A p.R512S | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54667341; called by muse, mutect2, varscan2
- KIR2DL4 | c.506C>A p.A169D (on ENST00000396284; = p.A130D on NM_001080770.2) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777884290; called by muse, varscan2
- KIR3DL3 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs1195198227; called by muse, varscan2
- KL | c.1647G>T p.W549C | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66309658; called by muse, mutect2, varscan2
- KLK4 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 104/405 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100133491; called by mutect2, varscan2
- KRTAP19-5 | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV61858185; called by muse, mutect2, varscan2
- LAMA1 | c.3382C>T p.Q1128* | Nonsense Mutation (SNP) | VAF 23/329 reads (7%) | catalogued as COSV67543639; called by muse, mutect2
- LRP1B | c.12261G>T p.W4087C | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1019002133, COSV101251513; called by muse, mutect2, varscan2
- MAGED1 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV58516678; called by muse, mutect2, varscan2
- MCF2L2 | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs375053168; called by muse, mutect2, varscan2
- MDGA2 | c.12G>C p.W4C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.883); catalogued as rs1274705210; called by muse, mutect2
- MMP16 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.06); catalogued as COSV54154656; called by muse, varscan2
- MROH2A | c.2066G>C p.R689P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV67681918; called by muse, mutect2, varscan2
- MROH2B | c.2084G>T p.S695I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV101270634; called by muse, varscan2
- MTNR1A | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 56/427 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1483013458, COSV56154949, COSV56157519; called by muse, mutect2, varscan2
- MTOR | c.3602G>A p.R1201Q | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs975845561, COSV63876368; called by muse, mutect2, varscan2
- MYH13 | c.4562C>T p.A1521V | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs777192178, COSV104383333; called by muse, mutect2, varscan2
- MYH4 | c.2896G>T p.A966S | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV55117243; called by muse, mutect2, varscan2
- MYH4 | c.2135G>T p.G712V | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55115962; called by muse, varscan2
- MYH4 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 40/169 reads (24%) | catalogued as COSV99702185; called by muse, varscan2
- MYO1G | c.2368G>T p.A790S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs755972612, COSV51856225; called by muse, mutect2, varscan2
- NEK9 | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs954321670, COSV53129345; called by muse, mutect2, varscan2
- NPAS3 | c.2495C>T p.A832V (on ENST00000356141 / NM_001164749.2; = p.A800V on NM_022123.3) | Missense Mutation (SNP) | VAF 127/376 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1350804865; called by muse, mutect2, varscan2
- NWD2 | c.4544G>A p.R1515Q | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); catalogued as rs772847080; called by muse, mutect2
- OR10Q1 | c.398C>A p.P133Q | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57469961; called by muse, mutect2, varscan2
- OR10X1 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.043); catalogued as COSV100936665; called by muse, mutect2
- OR1A2 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275162716, COSV67936330; called by mutect2, varscan2
- OR2L2 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV63550503, COSV63550599; called by mutect2, varscan2
- OR2M5 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1320736496, COSV63546353; called by muse, mutect2
- OR2T33 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100532112; called by muse, mutect2
- OR4B1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58882172, COSV58882854; called by muse, varscan2
- OR5T3 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as COSV57380398; called by muse, mutect2, varscan2
- OR8D2 | c.518C>A p.T173K | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as rs151287996; called by muse, mutect2, varscan2
- OTC | c.842T>C p.F281S | Missense Mutation (SNP) | VAF 106/379 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM065363; called by muse, mutect2, varscan2
- OTOG | c.2566G>A p.G856R | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867715728, COSV61131624; called by muse, mutect2
- PCDH17 | c.2208G>T p.E736D | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV64975208; called by muse, mutect2, varscan2
- PCDH17 | c.3050C>A p.P1017H | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV64978313; called by muse, mutect2, varscan2
- PCDHA1 | c.2000T>C p.V667A | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as rs369402851; called by muse, varscan2
- PCDHB8 | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 83/520 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99176242; called by muse, mutect2, varscan2
- PCDHGB2 | c.1954C>A p.P652T | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53902626; called by muse, mutect2, varscan2
- PEAK1 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1450979033; called by muse, mutect2, varscan2
- PIK3CG | c.2383G>A p.A795T | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs945222564, COSV63246325; called by muse, mutect2, varscan2
- PRAMEF6 | c.1322G>T p.R441I | Missense Mutation (SNP) | VAF 124/1047 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.975); catalogued as COSV61910063; called by muse, mutect2, varscan2
- PSG2 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750765678; called by muse, mutect2
- PTGES3L-AARSD1 | c.895G>T p.V299L (on ENST00000421990 / NM_001136042.2; = p.V281L on NM_025267.3) | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV64182062; called by muse, mutect2, varscan2
- PTPN5 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV62125638; called by muse, mutect2, varscan2
- PTPRT | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61969812; called by muse, mutect2, varscan2
- PTPRZ1 | c.2863G>T p.G955C | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as rs763354591, COSV66444072; called by muse, mutect2, varscan2
- RAG2 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 49/382 reads (13%) | catalogued as CM114604, COSV57559138; called by muse, mutect2, varscan2
- RELN | c.3270A>T p.E1090D | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV100634941; called by muse, mutect2
- RGS18 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV99054850; called by muse, mutect2, varscan2
- RGS9BP | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs749442416, COSV60130716; called by muse, mutect2, varscan2
- RPUSD1 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as rs775974460; called by muse, mutect2, varscan2
- RSBN1 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54731075; called by mutect2, varscan2
- SACS | c.11123C>T p.P3708L | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs376708955; called by muse, mutect2, varscan2
- SALL1 | c.2455G>T p.D819Y | Missense Mutation (SNP) | VAF 37/386 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51757970; called by muse, mutect2
- SARDH | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV100898464, COSV64100769; called by muse, mutect2
- SETBP1 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1356624472; called by muse, mutect2, varscan2
- SGK2 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58312896, COSV58313460, COSV58314511; called by muse, mutect2, varscan2
- SIM1 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs755172740, COSV53490281, COSV53495038; called by muse, mutect2, varscan2
- SLC22A16 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV57927988; called by muse, mutect2, varscan2
- SLC5A8 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.26); catalogued as rs781620466; called by muse, mutect2, varscan2
- SLC6A13 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58257807; called by muse, mutect2, varscan2
- SLC9C2 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs779781888; called by muse, mutect2, varscan2
- SLITRK3 | c.2476C>A p.Q826K | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.857); catalogued as COSV53851386; called by muse, mutect2, varscan2
- SNAPIN | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV62626788; called by muse, mutect2, varscan2
- SPTAN1 | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1264844049, COSV63989991; called by muse, mutect2
- SSTR3 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100142943; called by muse, mutect2
- SYT14 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs1460465597, COSV99654268; called by muse, mutect2, varscan2
- TAF1L | c.4360C>A p.R1454S | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.501); catalogued as COSV54260912; called by muse, mutect2, varscan2
- TARM1 | c.166C>T p.R56* (on ENST00000616041 / NM_001330650.1; = p.R48* on NM_001135686.3) | Nonsense Mutation (SNP) | VAF 26/216 reads (12%) | catalogued as rs1335591843, COSV71524846; called by muse, mutect2, varscan2
- TENM1 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 11/124 reads (9%) | catalogued as COSV64425669; called by muse, mutect2
- TFRC | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs535259536; called by muse, mutect2, varscan2
- TLE2 | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV53580232, COSV99504331; called by muse, mutect2
- TMPRSS2 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs781089181, COSV59828772; called by muse, mutect2, varscan2
- TNFRSF8 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.488); catalogued as rs777521542; called by muse, mutect2, varscan2
- TNNT1 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 97/421 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV52571387; called by muse, mutect2, varscan2
- TP53 | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 129/438 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAM1L1 | c.777G>C p.L259F | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as COSV100162287; called by muse, mutect2, varscan2
- TRPS1 | c.3634G>C p.E1212Q (on ENST00000220888 / NM_001330599.2; = p.E1225Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/568 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV99629255; called by muse, mutect2
- UNC5C | c.1466C>A p.T489N | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as COSV71662391; called by muse, mutect2
- USP32 | c.3100C>T p.R1034* | Nonsense Mutation (SNP) | VAF 71/284 reads (25%) | catalogued as COSV56273852; called by muse, mutect2, varscan2
- VAV1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58391393; called by muse, mutect2, varscan2
- ZFAND5 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52988387; called by muse, mutect2, varscan2
- ZNF106 | c.1888C>G p.R630G | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55516701; called by muse, mutect2
- ZNF648 | c.1360G>T p.G454C | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776836246; called by muse, mutect2, varscan2
- ZNF738 | c.4-1G>C p.X2_splice | Splice Site (SNP) | VAF 43/273 reads (16%) | catalogued as COSV100210527; called by muse, mutect2, varscan2
- AADACL4 | c.434T>A p.V145E | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ABCA4 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AC138647.1 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACACB | c.2062G>T p.A688S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.971); called by muse, mutect2
- ACAN | c.4268C>A p.A1423D | Missense Mutation (SNP) | VAF 76/436 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.962); called by muse, varscan2
- ACTRT2 | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAMTS1 | c.2205-1G>T p.X735_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.1235A>T p.H412L | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTSL3 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.864G>T p.W288C | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AGBL2 | c.1664G>T p.C555F | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- AHNAK2 | c.11528A>C p.Q3843P | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- AHNAK2 | c.11526G>T p.M3842I | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- AHNAK2 | c.9053A>T p.Q3018L | Missense Mutation (SNP) | VAF 13/353 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2
- AL645922.1 | c.239del p.S80Lfs*111 | Frame Shift Del (DEL) | VAF 38/345 reads (11%) | called by mutect2, pindel, varscan2
- ALLC | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- AMBP | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- AMER3 | c.2498G>T p.R833L | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPD2 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.122); called by muse, mutect2
- ANK2 | c.8071C>A p.P2691T | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK3 | c.10097G>A p.G3366E | Missense Mutation (SNP) | VAF 35/343 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APEX2 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- APEX2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ARHGEF38 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMH4 | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); called by muse, mutect2
- ASPM | c.4211G>T p.W1404L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ASTL | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ATP1B4 | c.559C>A p.Q187K (on ENST00000218008 / NM_001142447.3; = p.Q183K on NM_012069.5) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ATP8A2 | c.507+1G>T p.X169_splice | Splice Site (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2
- BCCIP | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.078); called by muse, mutect2
- BCL11A | c.796G>T p.V266L (on ENST00000335712 / NM_001365609.1; = p.V300L on NM_018014.4) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- BCORL1 | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- BPIFB2 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- BRWD3 | c.5335A>T p.T1779S | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- BRWD3 | c.2983G>A p.V995I | Missense Mutation (SNP) | VAF 15/409 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.033); called by muse, mutect2
- BTBD7 | c.3124del p.A1042Qfs*19 | Frame Shift Del (DEL) | VAF 123/349 reads (35%) | called by mutect2, pindel, varscan2
- C11orf24 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C19orf38 | c.326A>T p.N109I | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CACNA1A | c.4117G>C p.V1373L | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- CACNA1F | c.2419+1G>C p.X807_splice | Splice Site (SNP) | VAF 16/349 reads (5%) | called by muse, mutect2
- CALCRL | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK2B | c.1340-1G>T p.X447_splice | Splice Site (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- CAMKV | c.430A>T p.R144W | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARD6 | c.1809G>T p.K603N | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CASS4 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC168 | c.10220C>G p.S3407C | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.957); called by muse, varscan2
- CCDC7 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CCT6A | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CDC45 | c.1474G>T p.V492L | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CDH12 | c.2206C>A p.L736M | Missense Mutation (SNP) | VAF 34/514 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH23 | c.8983C>G p.H2995D | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CDH6 | c.1251C>A p.V417= | Splice Region (SNP) | VAF 26/138 reads (19%) | called by muse, varscan2
- CDK5RAP1 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CFAP99 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CHD5 | c.3199T>A p.Y1067N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRM4 | c.482T>A p.F161Y | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHRNA3 | c.518G>C p.C173S | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA7 | c.468G>T p.W156C | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CHST8 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- CKAP5 | c.4910G>T p.G1637V (on ENST00000529230 / NM_001008938.4; = p.G1577V on NM_014756.3) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLCN4 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CLSPN | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- CMTR1 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP2 | c.2984C>A p.A995E | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- COL14A1 | c.3097C>A p.L1033M | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL15A1 | c.2859A>T p.K953N | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- COL4A6 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2
- COL6A1 | c.931-2A>T p.X311_splice | Splice Site (SNP) | VAF 77/333 reads (23%) | called by muse, mutect2, varscan2
- COL6A2 | c.2547C>A p.F849L | Missense Mutation (SNP) | VAF 101/417 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- COPA | c.3476A>G p.N1159S | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRB2 | c.2669G>T p.G890V | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- CSMD3 | c.9247G>A p.D3083N (on ENST00000297405 / NM_001363185.1; = p.D2914N on NM_052900.3) | Missense Mutation (SNP) | VAF 28/688 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- CSMD3 | c.7156A>C p.S2386R (on ENST00000297405 / NM_001363185.1; = p.S2282R on NM_052900.3) | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2
- CST8 | c.232-1G>C p.X78_splice | Splice Site (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- CT47B1 | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 36/526 reads (7%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CWF19L2 | c.1921G>T p.V641F | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CYP26C1 | c.560C>G p.A187G | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CYP4A22 | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- DAB1 | c.1688C>T p.A563V (on ENST00000371231; = p.A530V on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DCHS2 | c.2039A>T p.H680L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.468); called by mutect2, varscan2
- DCSTAMP | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 40/471 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHX15 | c.1055T>A p.L352H | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DOCK2 | c.3666-4A>T | Splice Region (SNP) | VAF 24/131 reads (18%) | called by muse, mutect2, varscan2
- DOCK7 | c.6149G>T p.S2050I (on ENST00000635253 / NM_001367561.1; = p.S2019I on NM_033407.3) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DPP9 | c.1404G>T p.W468C (on ENST00000598800; = p.W497C on NM_139159.5) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); called by muse, mutect2
- DPP9 | c.1403G>T p.W468L (on ENST00000598800; = p.W497L on NM_139159.5) | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2
- DPYS | c.1267G>T p.V423F | Missense Mutation (SNP) | VAF 139/396 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DSG1 | c.1457T>C p.F486S | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC1I1 | c.1361A>C p.N454T | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2
- DYNC1I2 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYRK2 | c.1157G>C p.R386P (on ENST00000344096 / NM_006482.3; = p.R313P on NM_003583.4) | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EEF1D | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EEF2K | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEFSEC | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFHB | c.1672G>T p.V558F | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF2AK4 | c.2918A>T p.K973M | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ELK4 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 88/352 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ENAM | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ENAM | c.398C>A p.P133Q | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ENDOD1 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ENPEP | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EQTN | c.376+1G>A p.X126_splice | Splice Site (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- ERICH3 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ESX1 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2
- EYS | c.4983G>T p.L1661F | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM107A | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 46/316 reads (15%) | called by mutect2, varscan2
- FAM47C | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
- FAM71B | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FBXO5 | c.851T>A p.I284N | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCHO1 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FEZ1 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FEZF1 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FOXA2 | c.875G>T p.G292V (on ENST00000377115 / NM_153675.3; = p.G298V on NM_021784.5) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); called by muse, mutect2
- FOXI2 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2
- FSIP2 | c.9176A>C p.N3059T | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD1 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- GAK | c.3487G>C p.G1163R | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAREM1 | c.1943G>C p.R648T (on ENST00000269209 / NM_001242409.2; = p.R647T on NM_022751.3) | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GBP4 | c.286T>A p.W96R | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GDA | c.614G>T p.R205I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GK3P | c.269T>A p.V90D | Missense Mutation (SNP) | VAF 68/389 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GPAT3 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GPR119 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GPR153 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- GPR3 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- GSC | c.26A>T p.D9V | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GZMM | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HEPN1 | c.208T>A p.W70R | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIVEP3 | c.665G>T p.C222F | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNF4G | c.106T>G p.F36V (on ENST00000354370 / NM_001330561.2; = p.F83V on NM_004133.5) | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HRH1 | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HTN3 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IGHV3-48 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGLC7 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- IGLV3-9 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- IL18RAP | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IL1R1 | c.720G>T p.L240F | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IL21R | c.291C>A p.N97K | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2
- INPP5J | c.2036C>T p.T679I (on ENST00000331075 / NM_001284285.2; = p.T311I on NM_001002837.2) | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGA11 | c.2464C>G p.L822V | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- ITGAM | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- JPH1 | c.1791A>T p.K597N | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- KAT2B | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- KBTBD13 | c.692A>T p.Y231F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by mutect2, varscan2
- KCNH7 | c.1332T>A p.C444* | Nonsense Mutation (SNP) | VAF 73/274 reads (27%) | called by muse, mutect2, varscan2
- KCNU1 | c.1599C>A p.D533E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDELR2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, varscan2
- KDR | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA2026 | c.6085_6096del p.P2029_S2032del | In Frame Del (DEL) | VAF 14/164 reads (9%) | called by mutect2, pindel
- KNDC1 | c.3352C>A p.Q1118K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP19-2 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- KRTAP23-1 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- LAMB2 | c.701C>G p.S234* | Nonsense Mutation (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- LAS1L | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2
- LCP1 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LGALS16 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- LMX1A | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 52/244 reads (21%) | called by muse, mutect2, varscan2
- LOXL1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPIN3 | c.1664+2T>A p.X555_splice | Splice Site (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- LRP1B | c.12139G>T p.G4047W | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LRRC7 | c.3877A>T p.T1293S (on ENST00000651989 / NM_001370785.2; = p.T1260S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- LRRIQ3 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- LYST | c.1534C>T p.H512Y | Missense Mutation (SNP) | VAF 18/515 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAGEA6 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- MAGEE1 | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 97/255 reads (38%) | called by muse, mutect2, varscan2
- MAP2 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- MAP4K3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MARK1 | c.1323G>T p.Q441H | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MBL2 | c.693G>T p.W231C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MFSD13A | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD8 | c.1201dup p.C401Lfs*4 | Frame Shift Ins (INS) | VAF 59/419 reads (14%) | called by mutect2, pindel, varscan2
- MINPP1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 100/446 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP16 | c.1092G>C p.W364C | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, varscan2
- MOCS1 | c.1287_1288insA p.P430Tfs*34 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | called by mutect2, pindel
- MROH1 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 246/669 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MUC16 | c.4460C>A p.A1487D | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- MUC17 | c.3684C>A p.H1228Q | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.12428C>A p.T4143K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MXRA5 | c.6127G>T p.A2043S | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MYCN | c.946A>G p.S316G | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYLK | c.2186C>A p.S729* | Nonsense Mutation (SNP) | VAF 43/302 reads (14%) | called by muse, mutect2, varscan2
- MYO15B | c.3215G>T p.R1072L | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MYO6 | c.3755C>T p.A1252V (on ENST00000369981; = p.A1242V on NM_004999.4) | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELL2 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NF1 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- NKX1-1 | c.872C>A p.S291Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- NLRP13 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 23/172 reads (13%) | called by muse, mutect2, varscan2
- NLRP14 | c.2292G>T p.R764S | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP3 | c.2664-3C>A | Splice Region (SNP) | VAF 92/337 reads (27%) | called by muse, mutect2, varscan2
- NOL10 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- NPAP1 | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NPAS3 | c.2303G>T p.G768V (on ENST00000356141 / NM_001164749.2; = p.G736V on NM_022123.3) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTNG1 | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- NUP85 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NXPH4 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGDH | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- OR10G8 | c.928A>T p.S310C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- OR10Z1 | c.325T>A p.C109S | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR11H2 | c.621C>A p.S207R (on ENST00000556246; = p.S218R on NM_001197287.1) | Missense Mutation (SNP) | VAF 31/468 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2
- OR2AK2 | c.418A>T p.I140F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR5AN1 | c.701del p.G234Afs*13 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | called by mutect2, pindel, varscan2
- OR5AP2 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D16 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); called by muse, mutect2
- OR8I2 | c.656T>G p.I219S | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8K5 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- OTOGL | c.1105T>A p.C369S (on ENST00000547103; = p.C360S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAN2 | c.70G>C p.V24L | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDH10 | c.2387C>A p.P796H | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PCDH8 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- PCDHB7 | c.2177C>A p.P726H | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PCDHGA12 | c.2654T>A p.L885Q | Missense Mutation (SNP) | VAF 57/429 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGB6 | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCLO | c.5896A>T p.N1966Y | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PCSK1 | c.2047C>A p.Q683K | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDZD4 | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- PEG3 | c.1643C>G p.P548R | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PEX19 | c.875G>C p.S292T | Missense Mutation (SNP) | VAF 121/465 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PHF8 | c.1561C>A p.P521T (on ENST00000357988 / NM_001184896.1; = p.P485T on NM_015107.3) | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- PHKB | c.2272A>G p.K758E | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PIEZO2 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PIK3AP1 | c.1480A>G p.M494V | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- PIK3CD | c.2101C>A p.L701M | Missense Mutation (SNP) | VAF 107/473 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PJA1 | c.1267G>T p.A423S (on ENST00000361478 / NM_145119.4; = p.A235S on NM_022368.5) | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2
- PKN3 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1277T>A p.I426K (on ENST00000611850; = p.I427K on NM_005396.5) | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- POLD2 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- POP1 | c.621G>C p.W207C | Missense Mutation (SNP) | VAF 158/469 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEJ | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- PPL | c.5110A>G p.N1704D | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PPP1R3A | c.803C>A p.T268K | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PRCP | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.19); called by muse, mutect2
- PRDX2 | c.288G>T p.L96F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PRKCG | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, mutect2
- PRRC2A | c.803A>T p.Q268L | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PRRC2B | c.3800G>T p.G1267V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PRSS8 | c.86-1G>T p.X29_splice | Splice Site (SNP) | VAF 22/187 reads (12%) | called by mutect2, varscan2
- PSG11 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PSMC2 | c.845-1G>T p.X282_splice | Splice Site (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- PTBP1 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PUS7L | c.266A>G p.H89R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- RALGAPA1 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RALY | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- RANGAP1 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2
- RAPGEF2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- RBM20 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 107/457 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RBM20 | c.2123C>A p.A708E | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- RC3H2 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- RCOR1 | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RCSD1 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- RELN | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- REPS2 | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.099); called by muse, mutect2
- RFX6 | c.1024T>G p.L342V | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- RGPD1 | c.3973T>A p.L1325I (on ENST00000409776; = p.L1333I on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- RNPEPL1 | c.1730_1741+9del p.X577_splice | Splice Site (DEL) | VAF 17/189 reads (9%) | called by mutect2, pindel
- ROBO4 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, varscan2
- RSPH6A | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RTN4RL1 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RUNX1 | c.958A>G p.M320V (on ENST00000344691 / NM_001001890.3; = p.M347V on NM_001754.5) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUNX1T1 | c.1057G>T p.E353* (on ENST00000265814 / NM_001198628.1; = p.E326* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/292 reads (18%) | called by muse, mutect2, varscan2
- RYR2 | c.2726A>G p.D909G | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SCAF1 | c.2971G>T p.D991Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN7A | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- SEBOX | c.160T>A p.W54R | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB13 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- SERPINB13 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- SEZ6L2 | c.1412A>T p.H471L (on ENST00000308713 / NM_001114099.3; = p.H401L on NM_012410.4) | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2
- SGO1 | c.711A>G p.I237M | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SGO2 | c.3553C>T p.Q1185* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- SH2D5 | c.463del p.A155Hfs*15 (on ENST00000444387 / NM_001103161.2; = p.A71Hfs*15 on NM_001103160.2) | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | called by mutect2, pindel*, varscan2
- SHPRH | c.4326G>T p.Q1442H (on ENST00000275233 / NM_001042683.3; = p.Q1446H on NM_173082.3) | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2
- SIRPA | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.012); called by muse, varscan2
- SLC16A1 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC19A1 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 49/468 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A26 | c.705A>T p.A235= | Splice Region (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- SLC30A10 | c.1395C>G p.D465E | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- SLC39A12 | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A13 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SLC8A1 | c.1127del p.G376Afs*4 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.2386C>G p.Q796E | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- SNX22 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOAT2 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SORCS3 | c.2231C>G p.P744R | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SOX17 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- SP7 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.25); called by muse, varscan2
- SPIDR | c.1686G>C p.R562S | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- SPINT1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPOCK1 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTA1 | c.5814T>G p.D1938E | Missense Mutation (SNP) | VAF 115/461 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SRCAP | c.3741G>T p.Q1247H | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- STRAP | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SULF1 | c.1981A>G p.R661G | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYP | c.607A>T p.T203S | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAAR9 | c.897T>A p.C299* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2
- TADA2A | c.496del p.A166Pfs*22 | Frame Shift Del (DEL) | VAF 50/249 reads (20%) | called by mutect2, pindel, varscan2
- TAF1L | c.5184_5186dup p.E1728dup | In Frame Ins (INS) | VAF 36/303 reads (12%) | called by mutect2, varscan2
- TAF1L | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.005); called by muse, mutect2
- TAP1 | c.1558-6C>G | Splice Region (SNP) | VAF 52/314 reads (17%) | called by muse, mutect2, varscan2
- TBXA2R | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCP1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TICAM1 | c.1393A>T p.S465C | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TKTL2 | c.1541T>G p.V514G | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLL1 | c.1558C>A p.L520M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TLR5 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TLR7 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR7 | c.2249G>C p.R750P | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TMEM132D | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- TMEM140 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- TMEM198 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by mutect2, varscan2
- TMEM259 | c.896T>A p.M299K | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- TOX2 | c.1375A>C p.S459R (on ENST00000358131 / NM_001098798.2; = p.S435R on NM_032883.3) | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, varscan2
- TPD52 | c.566G>T p.G189V (on ENST00000379097 / NM_001025252.3; = p.G149V on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TRAPPC5 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- TRIM72 | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2
- TRO | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2
- TRPM2 | c.3549+1G>A p.X1183_splice | Splice Site (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- TSLP | c.62A>T p.Q21L | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTC30A | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TTN | c.57689T>C p.L19230P (on ENST00000591111; = p.L11806P on NM_003319.4) | Missense Mutation (SNP) | VAF 16/371 reads (4%) | PolyPhen probably damaging (0.939); called by muse, mutect2
- TULP4 | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.206T>G p.V69G | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- UBE2F | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBE3C | c.3028A>G p.K1010E | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- UGGT1 | c.4132G>C p.A1378P | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- UGT1A8 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UQCRFS1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- URB1 | c.1622G>T p.C541F | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- USH2A | c.10457T>A p.L3486H | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.115); called by muse, varscan2
- USP26 | c.1669C>G p.P557A | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- UTP25 | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 20/367 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2
- VPS13B | c.5567T>G p.L1856* | Nonsense Mutation (SNP) | VAF 24/538 reads (4%) | called by muse, mutect2
- VWCE | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- WDR64 | c.3100C>T p.Q1034* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2, varscan2
- WWP2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- XRN1 | c.3083A>T p.Q1028L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.148); called by muse, varscan2
- ZBBX | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZC3H14 | c.80-2A>T p.X27_splice | Splice Site (SNP) | VAF 109/281 reads (39%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7369C>A p.Q2457K | Missense Mutation (SNP) | VAF 60/398 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF135 | c.340G>A p.E114K (on ENST00000313434 / NM_001289401.2; = p.E126K on NM_003436.4) | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF208 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ZNF275 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.223); called by muse, mutect2
- ZNF382 | c.1340A>G p.Q447R | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF492 | c.997G>C p.G333R | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2
- ZNF521 | c.2683T>A p.Y895N | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF527 | c.1762G>T p.G588W | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF562 | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF599 | c.424del p.H142Tfs*9 | Frame Shift Del (DEL) | VAF 48/249 reads (19%) | called by mutect2, pindel, varscan2
- ZNF729 | c.2599C>G p.L867V | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, varscan2
- ZNF736 | c.757G>T p.G253* | Nonsense Mutation (SNP) | VAF 32/168 reads (19%) | called by muse, mutect2, varscan2
- ZNF804A | c.2027C>A p.T676K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZNF804A | c.2322A>T p.Q774H | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZNF804A | c.3034G>A p.V1012I | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF804B | c.725C>G p.T242R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ZP2 | c.1466A>T p.K489M | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZPLD1 | c.644T>A p.V215E (on ENST00000466937 / NM_001329788.1; = p.V231E on NM_175056.2) | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZSCAN4 | c.1088C>G p.T363R | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ABHD16B | c.171G>A p.A57= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as rs1228159499; called by muse, mutect2, varscan2
- ACAN | c.4269C>T p.A1423= | Silent (SNP) | VAF 81/438 reads (18%) | catalogued as rs1336400959, COSV100718170; called by muse, varscan2
- ACTC1 | c.63C>A p.A21= | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- AGMO | c.282G>T p.L94= | Silent (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- AKAIN1 | c.156G>T p.R52= | Silent (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- ANK2 | c.1320C>T p.F440= | Silent (SNP) | VAF 30/412 reads (7%) | catalogued as rs1202935205; called by muse, mutect2
- ANK2 | c.10530C>A p.A3510= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- ANKFN1 | c.411C>G p.G137= | Silent (SNP) | VAF 9/239 reads (4%) | called by muse, mutect2
- ANO4 | c.2547G>A p.S849= (on ENST00000392977 / NM_001286615.2; = p.S814= on NM_178826.4) | Silent (SNP) | VAF 22/209 reads (11%) | catalogued as rs762658538, COSV100151278; called by muse, mutect2, varscan2
- ARC | c.966C>A p.I322= | Silent (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- ARHGAP4 | c.1104C>A p.R368= | Silent (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- ARMCX2 | c.996G>A p.L332= | Silent (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- ASB5 | c.732C>A p.S244= | Silent (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- ASMTL | c.369A>T p.T123= | Silent (SNP) | VAF 68/252 reads (27%) | called by muse, mutect2, varscan2
- ATE1 | c.717A>G p.P239= | Silent (SNP) | VAF 72/386 reads (19%) | catalogued as rs757349774; called by muse, mutect2, varscan2
- ATP13A2 | c.2745C>T p.C915= | Silent (SNP) | VAF 32/650 reads (5%) | catalogued as rs372361807; called by muse, mutect2
- BMS1 | c.3198G>T p.G1066= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- C6orf58 | c.351A>T p.G117= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- CASKIN1 | c.405A>T p.L135= | Silent (SNP) | VAF 32/282 reads (11%) | called by muse, mutect2, varscan2
- CATSPERD | c.2265C>A p.I755= | Silent (SNP) | VAF 69/309 reads (22%) | called by muse, mutect2, varscan2
- CCDC168 | c.9489A>G p.L3163= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as rs1186037102; called by muse, mutect2
- CD1C | c.675T>C p.C225= | Silent (SNP) | VAF 56/222 reads (25%) | called by muse, mutect2, varscan2
- CDH23 | c.870C>T p.S290= | Silent (SNP) | VAF 57/281 reads (20%) | catalogued as rs375292899; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CFAP43 | c.2580G>T p.V860= | Silent (SNP) | VAF 47/262 reads (18%) | called by muse, mutect2, varscan2
- CFAP91 | c.1191C>T p.N397= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as rs112688497; called by muse, mutect2, varscan2
- CHST7 | c.453C>A p.G151= | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as COSV52100142; called by muse, mutect2
- CLCN1 | c.2019A>T p.A673= | Silent (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
- CLDN34 | c.183G>T p.R61= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- CNGA1 | c.1449G>T p.L483= | Silent (SNP) | VAF 16/249 reads (6%) | called by muse, mutect2
- CNTN1 | c.2565C>T p.N855= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as rs927764904; called by muse, mutect2
- CNTNAP4 | c.1179T>A p.S393= | Silent (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2, varscan2
- COL19A1 | c.576T>C p.I192= | Silent (SNP) | VAF 41/222 reads (18%) | called by muse, mutect2, varscan2
- COL22A1 | c.3177A>G p.K1059= | Silent (SNP) | VAF 17/223 reads (8%) | called by muse, mutect2
- COL6A3 | c.3561C>T p.A1187= | Silent (SNP) | VAF 46/348 reads (13%) | called by muse, mutect2, varscan2
- COL6A6 | c.5427C>A p.A1809= | Silent (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- COL9A1 | c.1830G>T p.G610= | Silent (SNP) | VAF 24/494 reads (5%) | catalogued as rs1414945380; called by muse, mutect2
- CROCC2 | c.1164C>A p.S388= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- CROCC2 | c.2160G>A p.Q720= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- CSMD3 | c.1449C>A p.S483= (on ENST00000297405 / NM_001363185.1; = p.S379= on NM_052900.3) | Silent (SNP) | VAF 49/357 reads (14%) | called by muse, mutect2, varscan2
- CSRNP3 | c.1194C>G p.G398= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- DCLK1 | c.912T>A p.R304= | Silent (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- DISP3 | c.141G>T p.R47= | Silent (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- DPYS | c.18G>T p.R6= | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- ECSIT | c.198C>A p.T66= | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- EPHA3 | c.558T>G p.V186= | Silent (SNP) | VAF 17/180 reads (9%) | called by muse, mutect2, varscan2
- EPPK1 | c.5829C>T p.P1943= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- F12 | c.405C>T p.C135= | Silent (SNP) | VAF 115/442 reads (26%) | catalogued as CM102609, COSV53693605; called by muse, mutect2, varscan2
- FBXL19 | c.246C>T p.L82= | Silent (SNP) | VAF 11/93 reads (12%) | called by muse, varscan2
- FBXO47 | c.624C>A p.A208= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2
- FCN2 | c.183C>A p.P61= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as rs1370164814; called by muse, mutect2, varscan2
- GCN1 | c.5325G>T p.V1775= | Silent (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- GJD2 | c.915C>T p.V305= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs937912303; called by muse, mutect2, varscan2
- GK2 | c.1089C>A p.A363= | Silent (SNP) | VAF 40/220 reads (18%) | called by muse, mutect2, varscan2
- GLDC | c.801A>G p.P267= | Silent (SNP) | VAF 46/390 reads (12%) | called by muse, mutect2, varscan2
- GPC3 | c.1707C>A p.A569= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- HAPLN1 | c.36C>A p.I12= | Silent (SNP) | VAF 48/191 reads (25%) | called by muse, mutect2, varscan2
- HGF | c.36G>A p.L12= | Silent (SNP) | VAF 44/347 reads (13%) | called by muse, mutect2, varscan2
- HOXA6 | c.657C>A p.S219= | Silent (SNP) | VAF 31/138 reads (22%) | called by muse, varscan2
- IGF2 | c.216G>A p.L72= (on ENST00000434045 / NM_001127598.3; = p.L16= on NM_000612.6) | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as COSV56098075; called by muse, mutect2, varscan2
- ITGAM | c.1266G>T p.G422= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV54933535; called by muse, mutect2, varscan2
- ITLN2 | c.777C>A p.A259= | Silent (SNP) | VAF 50/257 reads (19%) | called by muse, mutect2, varscan2
- KCNS2 | c.390C>A p.P130= | Silent (SNP) | VAF 93/499 reads (19%) | called by muse, mutect2, varscan2
- KCNT1 | c.135G>T p.A45= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs769898346; called by muse, mutect2, varscan2
- KCNT2 | c.214C>T p.L72= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- KIAA1328 | c.1326G>A p.K442= | Silent (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- KIRREL1 | c.1468C>A p.R490= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as COSV63289734; called by muse, mutect2, varscan2
- LAMC3 | c.3900G>C p.T1300= | Silent (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- LIN9 | c.1689A>C p.T563= (on ENST00000366808 / NM_001270410.2; = p.T508= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- LRRC10B | c.126G>A p.A42= | Silent (SNP) | VAF 39/150 reads (26%) | called by muse, mutect2, varscan2
- LRRC4C | c.778C>A p.R260= | Silent (SNP) | VAF 68/231 reads (29%) | catalogued as COSV53420745, COSV99537061; called by muse, mutect2, varscan2
- LRRTM4 | c.951G>T p.R317= | Silent (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- LTBP1 | c.2079G>C p.L693= (on ENST00000404816 / NM_206943.4; = p.L367= on NM_000627.4) | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs1180413780; called by muse, mutect2
- MAGEB6B | c.414C>A p.T138= | Silent (SNP) | VAF 28/263 reads (11%) | called by muse, mutect2, varscan2
- MKI67 | c.6945C>T p.D2315= | Silent (SNP) | VAF 31/293 reads (11%) | catalogued as rs1309027994; called by muse, mutect2, varscan2
- MMEL1 | c.6G>T p.G2= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- MOB2 | c.450C>T p.H150= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as rs766205043; called by muse, mutect2, varscan2
- MROH2A | c.2067G>T p.R689= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.36414A>C p.S12138= | Silent (SNP) | VAF 16/181 reads (9%) | called by muse, mutect2
- MUC16 | c.8229G>A p.S2743= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV101198441, COSV67443037; called by muse, mutect2
- MUC16 | c.4461T>A p.A1487= | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as COSV67466807; called by muse, varscan2
- MUC16 | c.4248T>A p.P1416= | Silent (SNP) | VAF 48/224 reads (21%) | called by muse, varscan2
- MUC16 | c.786A>G p.G262= | Silent (SNP) | VAF 12/165 reads (7%) | catalogued as COSV67459284; called by muse, mutect2
- MYO5B | c.2739A>G p.A913= | Silent (SNP) | VAF 128/413 reads (31%) | called by muse, mutect2, varscan2
- NAV3 | c.1182G>T p.R394= | Silent (SNP) | VAF 79/262 reads (30%) | catalogued as COSV57065957, COSV99893341; called by muse, mutect2, varscan2
- NEK9 | c.1116G>T p.R372= | Silent (SNP) | VAF 69/227 reads (30%) | called by muse, mutect2, varscan2
- NEUROD6 | c.363C>G p.V121= | Silent (SNP) | VAF 32/332 reads (10%) | called by muse, mutect2
- NLGN4X | c.1413C>A p.A471= | Silent (SNP) | VAF 29/460 reads (6%) | called by muse, mutect2
- NOX4 | c.1275C>T p.V425= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- OOSP2 | c.375T>C p.S125= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs1396517841, COSV53929937; called by muse, mutect2, varscan2
- OR10A3 | c.768T>C p.N256= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as rs138525938; called by muse, mutect2, varscan2
- OR13H1 | c.468T>C p.T156= | Silent (SNP) | VAF 41/231 reads (18%) | called by muse, mutect2, varscan2
- OR6B1 | c.618C>A p.I206= | Silent (SNP) | VAF 87/362 reads (24%) | catalogued as COSV101281629, COSV68770307; called by muse, mutect2, varscan2
- P2RY13 | c.531A>T p.P177= | Silent (SNP) | VAF 28/318 reads (9%) | called by muse, mutect2
- P4HA1 | c.57A>C p.P19= | Silent (SNP) | VAF 54/313 reads (17%) | called by muse, mutect2, varscan2
- PATL1 | c.981A>G p.P327= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs775290637; called by muse, mutect2
- PCDHA1 | c.2040G>T p.S680= | Silent (SNP) | VAF 62/244 reads (25%) | catalogued as COSV65377401; called by muse, varscan2
- PCDHA11 | c.1617G>T p.A539= | Silent (SNP) | VAF 158/637 reads (25%) | catalogued as rs544150374, COSV100246845; called by muse, mutect2, varscan2
- PCDHB10 | c.2244C>A p.S748= | Silent (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1242A>T p.T414= | Silent (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.513C>T p.P171= | Silent (SNP) | VAF 62/239 reads (26%) | called by muse, mutect2, varscan2
- PCMTD2 | c.444G>A p.G148= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV55061028; called by muse, mutect2, varscan2
- PDE3B | c.1842C>T p.F614= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- PGR | c.2766A>T p.A922= | Silent (SNP) | VAF 51/292 reads (17%) | called by muse, mutect2, varscan2
- PHF3 | c.4944G>A p.L1648= | Silent (SNP) | VAF 26/255 reads (10%) | called by muse, mutect2
- PKN1 | c.1386G>T p.L462= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV54399694; called by muse, mutect2, varscan2
- POLDIP2 | c.354T>A p.P118= | Silent (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- PPFIA3 | c.2103A>T p.G701= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- PPP1R3F | c.2091C>T p.V697= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- PPP2R1B | c.477A>T p.A159= | Silent (SNP) | VAF 81/347 reads (23%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.1371T>A p.T457= | Silent (SNP) | VAF 28/343 reads (8%) | called by muse, mutect2, varscan2
- PSEN1 | c.570C>T p.N190= | Silent (SNP) | VAF 79/233 reads (34%) | catalogued as rs1260743710, COSV56195723; called by muse, mutect2, varscan2
- PSG7 | c.943C>A p.R315= | Silent (SNP) | VAF 49/220 reads (22%) | catalogued as rs751567313; called by muse, mutect2, varscan2
- PTGDR2 | c.162C>T p.L54= | Silent (SNP) | VAF 43/267 reads (16%) | catalogued as rs1403628632; called by muse, mutect2, varscan2
- RAI14 | c.2319A>G p.L773= | Silent (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- RCAN1 | c.633G>T p.V211= | Silent (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- REG3A | c.87C>A p.P29= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV59408691; called by muse, mutect2, varscan2
- RENBP | c.1140C>G p.L380= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- RIMS2 | c.120C>A p.I40= | Silent (SNP) | VAF 18/187 reads (10%) | called by muse, mutect2
- RMI1 | c.1164A>G p.S388= | Silent (SNP) | VAF 31/223 reads (14%) | called by muse, mutect2, varscan2
- RNASE3 | c.237T>C p.V79= | Silent (SNP) | VAF 163/468 reads (35%) | called by muse, mutect2, varscan2
- RNF214 | c.465A>G p.P155= | Silent (SNP) | VAF 69/289 reads (24%) | called by muse, mutect2, varscan2
- RORA | c.807C>T p.S269= (on ENST00000335670 / NM_134261.3; = p.S294= on NM_002943.3) | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, varscan2
- RRP15 | c.741G>T p.T247= | Silent (SNP) | VAF 34/229 reads (15%) | catalogued as COSV65117329; called by muse, mutect2, varscan2
- RTL1 | c.2670G>T p.L890= | Silent (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- S100B | c.246T>A p.T82= | Silent (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.888G>T p.T296= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV55921765; called by muse, mutect2, varscan2
- SLC15A2 | c.1671T>C p.P557= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- SLC16A1 | c.1164C>A p.S388= | Silent (SNP) | VAF 71/277 reads (26%) | catalogued as COSV63710192; called by muse, mutect2, varscan2
- SPATA20 | c.2022C>T p.T674= (on ENST00000356488 / NM_001258372.1; = p.T690= on NM_022827.4) | Silent (SNP) | VAF 132/480 reads (28%) | catalogued as rs145311982; called by muse, mutect2, varscan2
- SPHKAP | c.1077G>T p.V359= | Silent (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.651G>T p.L217= | Silent (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- STAT2 | c.2082G>A p.R694= | Silent (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- THSD7B | c.4191G>T p.V1397= (on ENST00000272643; = p.V1395= on NM_001316349.2) | Silent (SNP) | VAF 50/176 reads (28%) | called by muse, mutect2, varscan2
- TMCC3 | c.189G>A p.K63= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as rs1214177918; called by muse, mutect2, varscan2
- TMEM217 | c.108C>T p.H36= | Silent (SNP) | VAF 71/269 reads (26%) | called by muse, mutect2, varscan2
- TNS1 | c.3414G>T p.P1138= | Silent (SNP) | VAF 25/267 reads (9%) | called by muse, mutect2
- TPTE | c.252T>C p.I84= (on ENST00000618007 / NM_199261.4; = p.I66= on NM_199259.4) | Silent (SNP) | VAF 23/294 reads (8%) | catalogued as rs1224516052; called by muse, mutect2
- TRO | c.1356G>T p.V452= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- TXNDC11 | c.1227G>T p.G409= (on ENST00000356957 / NM_001303447.2; = p.G382= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- URI1 | c.1410A>G p.L470= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV56349275; called by muse, mutect2, varscan2
- VPS72 | c.312G>T p.P104= | Silent (SNP) | VAF 85/370 reads (23%) | catalogued as rs752210930, COSV63166765, COSV63166797; called by muse, mutect2, varscan2
- WAPL | c.2082G>A p.L694= | Silent (SNP) | VAF 13/252 reads (5%) | called by muse, mutect2
- WRAP53 | c.546C>T p.S182= | Silent (SNP) | VAF 30/283 reads (11%) | called by muse, mutect2
- XIRP2 | c.4617A>G p.K1539= (on ENST00000628543; = p.K1714= on NM_152381.6) | Silent (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- ZDHHC15 | c.753A>G p.P251= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- ZFHX4 | c.816G>C p.G272= | Silent (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- ZNF20 | c.129G>T p.L43= | Silent (SNP) | VAF 24/226 reads (11%) | called by muse, varscan2
- ZNF563 | c.444A>G p.K148= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as rs139892393; called by muse, mutect2
- ZSCAN5C | c.1104C>T p.R368= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs190840407; called by muse, mutect2, varscan2
- ZYG11A | c.663T>C p.S221= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- AC008758.3 | n.677A>T | RNA (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5063G>T | RNA (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5062G>T | RNA (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2773G>A | RNA (SNP) | VAF 70/245 reads (29%) | called by muse, mutect2, varscan2
- AC034105.1 | n.61C>A | RNA (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2, varscan2
- AC099654.5 | n.39C>A | RNA (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- ACSM2B | c.597-155G>T | Intron (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- ADORA1 | c.342-135G>T | Intron (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- AMFR | c.*714G>T | 3'UTR (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2
- AMPD2 | c.719-25G>T | Intron (SNP) | VAF 33/141 reads (23%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499697 del AAG | 5'Flank (DEL) | VAF 17/155 reads (11%) | catalogued as rs1240098525; called by mutect2, pindel
- ARHGEF4 | chr2:130915487 A>T | 5'Flank (SNP) | VAF 50/212 reads (24%) | called by muse, mutect2, varscan2
- ARX | c.*103C>A | 3'UTR (SNP) | VAF 10/112 reads (9%) | catalogued as rs982588702; called by muse, mutect2
- BCAP31 | c.*26G>T | 3'UTR (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- C3orf18 | c.*568G>C | 3'UTR (SNP) | VAF 41/293 reads (14%) | called by muse, mutect2, varscan2
- CASP16P | chr16:3148397 G>A | 3'Flank (SNP) | VAF 20/231 reads (9%) | catalogued as rs1354443574; called by muse, mutect2
- CCDC196 | c.716-1809C>A | Intron (SNP) | VAF 57/242 reads (24%) | called by muse, mutect2, varscan2
- CCDC69 | c.49-7374G>T | Intron (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- CCNQP1 | n.218C>A | RNA (SNP) | VAF 127/442 reads (29%) | called by muse, mutect2, varscan2
- CDH8 | c.1536+44A>G | Intron (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- CHORDC1 | c.64+100C>T | Intron (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- CREB5 | chr7:28410411 C>A | 5'Flank (SNP) | VAF 97/405 reads (24%) | called by muse, mutect2, varscan2
- CTBP1 | c.195+284A>G | Intron (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- CUBN | c.593+254G>T | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101558309 C>A | 5'Flank (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101558310 C>A | 5'Flank (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- EPM2A | c.*1732T>C | 3'UTR (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- EYS | c.1766+2590C>A | Intron (SNP) | VAF 45/209 reads (22%) | called by muse, mutect2, varscan2
- FAM172BP | n.802G>T | RNA (SNP) | VAF 65/257 reads (25%) | called by muse, mutect2, varscan2
- FEZ1 | c.*61G>A | 3'UTR (SNP) | VAF 24/286 reads (8%) | called by muse, mutect2
- FMO6P | n.906-16G>T | Intron (SNP) | VAF 59/235 reads (25%) | called by mutect2, varscan2
- GALT | c.-18G>T | 5'UTR (SNP) | VAF 35/301 reads (12%) | called by muse, mutect2, varscan2
- GCK | c.*43G>T | 3'UTR (SNP) | VAF 24/224 reads (11%) | called by muse, mutect2
- GDA | c.*2376A>T | 3'UTR (SNP) | VAF 51/226 reads (23%) | catalogued as COSV99428921; called by muse, varscan2
- GFOD1 | c.253+16565C>T | Intron (SNP) | VAF 20/193 reads (10%) | called by muse, mutect2, varscan2
- GPR161 | chr1:168085126 A>G | 3'Flank (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- GRIK5 | c.245-458G>A | Intron (SNP) | VAF 20/247 reads (8%) | called by muse, mutect2
- HERC2P4 | n.479C>T | RNA (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.579G>T | RNA (SNP) | VAF 69/333 reads (21%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+2592G>A | Intron (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- KCNQ2 | c.1247+43G>T | Intron (SNP) | VAF 14/88 reads (16%) | catalogued as COSV60556204; called by muse, mutect2
- KDM3B | c.*5G>T | 3'UTR (SNP) | VAF 55/189 reads (29%) | called by muse, mutect2, varscan2
- KDM3B | c.*6G>T | 3'UTR (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- KIF1A | c.2555+981C>A | Intron (SNP) | VAF 54/187 reads (29%) | catalogued as COSV100241693; called by muse, mutect2, varscan2
- LINC02876 | n.498G>A | RNA (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- LRATD1 | c.*237C>G | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- MAFG | c.-13G>T | 5'UTR (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- MBD1 | c.393-16G>T | Intron (SNP) | VAF 102/444 reads (23%) | called by muse, mutect2, varscan2
- MLIP | c.613-11657C>A | Intron (SNP) | VAF 60/212 reads (28%) | called by muse, mutect2, varscan2
- MMGT1 | c.-21G>T | 5'UTR (SNP) | VAF 24/367 reads (7%) | called by muse, mutect2
- MYH16 | n.4090C>A | RNA (SNP) | VAF 61/262 reads (23%) | called by muse, mutect2, varscan2
- MYO1C | c.-11C>A | 5'UTR (SNP) | VAF 50/195 reads (26%) | catalogued as COSV100233982; called by muse, mutect2, varscan2
- MYO7B | c.6249+14C>A | Intron (SNP) | VAF 74/503 reads (15%) | called by muse, mutect2, varscan2
- NCAM1 | c.1826-3543C>A | Intron (SNP) | VAF 41/277 reads (15%) | called by muse, mutect2, varscan2
- NKAIN4 | c.54+217G>T | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- NRXN1 | c.833-32772T>A | Intron (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- OFCC1 | n.1692C>A | RNA (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- OOSP2 | c.348-184T>C | Intron (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- OR2A13P | n.823C>T | RNA (SNP) | VAF 62/242 reads (26%) | called by muse, mutect2, varscan2
- OR7E5P | n.163C>T | RNA (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- PATL2 | c.516-68G>T | Intron (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2394+12T>A | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, varscan2
- PGC | c.648-489G>T | Intron (SNP) | VAF 21/172 reads (12%) | catalogued as rs775120810; called by muse, mutect2, varscan2
- POLR2J4 | n.136G>T | RNA (SNP) | VAF 64/814 reads (8%) | called by muse, varscan2
- POM121L4P | n.664G>A | RNA (SNP) | VAF 63/778 reads (8%) | catalogued as rs1208837295; called by muse, mutect2
- PROKR2 | c.-30C>A | 5'UTR (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- PRR12 | c.51+155del | Intron (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- RABGAP1L | c.2212-11475G>T | Intron (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- RALYL | c.-24+597C>T | Intron (SNP) | VAF 21/386 reads (5%) | called by muse, mutect2
- REG1B | c.183+22G>T | Intron (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- RPGR | c.2520+483G>T | Intron (SNP) | VAF 10/84 reads (12%) | catalogued as rs1324776026; called by muse, mutect2, varscan2
- SDHA | c.1064+20A>T | Intron (SNP) | VAF 125/320 reads (39%) | called by muse, mutect2, varscan2
- SLC12A6 | c.2268-15C>T | Intron (SNP) | VAF 59/249 reads (24%) | catalogued as rs1325375207; called by muse, mutect2, varscan2
- SLC26A1 | c.*863C>A | 3'UTR (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- SLC27A4 | c.-144T>C | 5'UTR (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- SLC4A8 | c.2172+4868G>A | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- SREBF2 | c.2739-33G>T | Intron (SNP) | VAF 37/228 reads (16%) | called by muse, mutect2, varscan2
- SSPOP | n.8322C>T | RNA (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2, varscan2
- SSPOP | n.11016T>C | RNA (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- TDRD6 | c.-11G>T | 5'UTR (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
13 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 13 other) are not listed here.
